Somatic mutation profile of tumor specimen C3L-05299-04 (aliquot CPT0282200006) from CPTAC case C3L-05299, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 72.3 years (26,405 days).
Specimen C3L-05299-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d89fde3d-e03c-49c9-8bd5-783b5045c40d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05299-31 (Blood Derived Normal), aliquot CPT0282330002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc30b79f-c023-4ab4-88d7-efd3a9a9e3de

The open-access MAF lists 1,027 somatic variants for this specimen: 610 protein-altering or splice-affecting, 364 silent, 53 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 559, Silent 364, Nonsense Mutation 36, Intron 28, 5'UTR 9, 3'UTR 6, Splice Region 5, 5'Flank 5, Splice Site 3, 3'Flank 3, Translation Start Site 3, RNA 2.

Variants (750 of 1,027; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 168/506 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- PKP2 | c.1147C>T p.Q383* | Nonsense Mutation (SNP) | VAF 68/302 reads (23%) | catalogued as rs1057520650; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SYNE1 | c.1912C>T p.Q638* (on ENST00000367255 / NM_182961.4; = p.Q645* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 60/300 reads (20%) | catalogued as rs1554756035; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.3391G>A p.D1131N | Missense Mutation (SNP) | VAF 93/395 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55596397; called by muse, mutect2, varscan2
- ABCC9 | c.2968G>A p.G990R | Missense Mutation (SNP) | VAF 83/381 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.882); catalogued as rs868219603; called by muse, mutect2, varscan2
- ACE | c.1028G>A p.W343* | Nonsense Mutation (SNP) | VAF 180/818 reads (22%) | catalogued as rs200225958, CM120944, COSV52007657; called by muse, mutect2, varscan2
- ACOT12 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 48/259 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56897277; called by muse, mutect2, varscan2
- ACR | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 126/476 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.173); catalogued as rs1569123326; called by muse, mutect2, varscan2
- ACSM5 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 73/328 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776309636, COSV59375732; called by muse, mutect2, varscan2
- ADCY5 | c.3575G>A p.R1192Q | Missense Mutation (SNP) | VAF 81/309 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs148824947; called by muse, mutect2, varscan2
- ADGRF3 | c.1951G>A p.E651K (on ENST00000311519 / NM_001145168.1; = p.E452K on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 126/528 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as rs1381928630; called by muse, mutect2, varscan2
- ADGRV1 | c.4909C>T p.L1637F | Missense Mutation (SNP) | VAF 51/291 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.462); catalogued as rs1433152268; called by muse, mutect2, varscan2
- AGBL1 | c.2894G>A p.R965Q | Missense Mutation (SNP) | VAF 93/382 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1046025870, COSV66849337; called by muse, mutect2, varscan2
- ALDH2 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 60/305 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as rs1052140419; called by muse, mutect2, varscan2
- ALK | c.4249G>A p.D1417N | Missense Mutation (SNP) | VAF 91/403 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.706); catalogued as COSV66565813; called by muse, mutect2, varscan2
- ALOX12B | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 86/255 reads (34%) | SIFT tolerated (0.85); PolyPhen benign (0.027); catalogued as rs536446862, COSV59874293, COSV59875704; called by muse, mutect2, varscan2
- AMER3 | c.200A>G p.N67S | Missense Mutation (SNP) | VAF 115/523 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV58467937; called by muse, mutect2, varscan2
- APC | c.7049C>T p.S2350F | Missense Mutation (SNP) | VAF 87/433 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs75207119, COSV57389950; ClinVar: uncertain significance / other; called by muse, mutect2, varscan2
- APOB | c.13153C>T p.R4385C | Missense Mutation (SNP) | VAF 103/399 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs864309556, CM125433, COSV51949532; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOB | c.6181G>A p.D2061N | Missense Mutation (SNP) | VAF 74/316 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51926339; called by muse, mutect2, varscan2
- ARHGAP21 | c.229C>T p.Q77* | Nonsense Mutation (SNP) | VAF 62/246 reads (25%) | catalogued as COSV64542280; called by muse, mutect2, varscan2
- ARHGAP29 | c.1940G>A p.R647Q | Missense Mutation (SNP) | VAF 60/252 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as rs748894382, COSV53110021; called by muse, mutect2, varscan2
- ARHGEF26 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 92/445 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs1338542216; called by muse, mutect2
- ARMC5 | c.2195C>T p.S732F | Missense Mutation (SNP) | VAF 149/603 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.748); catalogued as rs1432603126; called by muse, mutect2, varscan2
- ARSL | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 111/269 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV101140446; called by muse, mutect2, varscan2
- ASXL3 | c.6371C>T p.S2124F | Missense Mutation (SNP) | VAF 91/424 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.87); catalogued as COSV52468932; called by muse, mutect2, varscan2
- ATXN7L3 | c.863C>T p.S288F (on ENST00000389384 / NM_001382309.1; = p.S295F on NM_001382308.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/373 reads (21%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100116055; called by muse, mutect2, varscan2
- AXIN1 | c.2393C>T p.T798I | Missense Mutation (SNP) | VAF 118/490 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs1488698142; called by muse, mutect2, varscan2
- BBS9 | c.2143G>A p.E715K (on ENST00000242067 / NM_001348036.1; = p.E675K on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/317 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.209); catalogued as COSV54167070; called by muse, mutect2, varscan2
- BCO1 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 73/273 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as COSV50728197; called by muse, mutect2, varscan2
- BCO1 | c.1477G>A p.D493N | Missense Mutation (SNP) | VAF 104/353 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV50730899; called by muse, mutect2, varscan2
- BMP5 | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 94/422 reads (22%) | catalogued as rs1396089139, COSV63701194; called by muse, mutect2, varscan2
- C20orf194 | c.1901C>T p.S634L | Missense Mutation (SNP) | VAF 70/315 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as rs374956285, COSV52694220; called by muse, mutect2, varscan2
- C2orf16 | c.81G>A p.M27I | Missense Mutation (SNP) | VAF 77/385 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV68843459; called by muse, mutect2, varscan2
- CA3 | c.280C>T p.H94Y | Missense Mutation (SNP) | VAF 143/419 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs868251349; called by muse, mutect2, varscan2
- CACNA1C | c.2218G>A p.G740R | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59762480; called by muse, mutect2, varscan2
- CACNA1E | c.5068G>A p.E1690K | Missense Mutation (SNP) | VAF 86/554 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.31); catalogued as rs569085430, COSV62390649; called by muse, varscan2
- CACNA1E | c.5089G>A p.D1697N | Missense Mutation (SNP) | VAF 94/491 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.149); catalogued as rs768500940, COSV62387967, COSV62424409; called by muse, varscan2
- CACNG5 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 110/786 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs758180109; called by muse, mutect2, varscan2
- CAMK2D | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 126/391 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); catalogued as COSV56441039; called by muse, mutect2, varscan2
- CCDC68 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 67/290 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.09); catalogued as rs1423113467, COSV61604108; called by muse, mutect2, varscan2
- CCDC73 | c.148C>T p.H50Y | Missense Mutation (SNP) | VAF 71/250 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs1462940314, COSV58795902; called by muse, mutect2, varscan2
- CD2 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 84/530 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); catalogued as COSV65644712; called by muse, mutect2, varscan2
- CD209 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 109/626 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.767); catalogued as COSV99214042; called by muse, mutect2, varscan2
- CDH12 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 107/380 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV101203390, COSV66397818; called by muse, mutect2, varscan2
- CDH6 | c.2234C>T p.S745F | Missense Mutation (SNP) | VAF 106/429 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54068910; called by muse, mutect2, varscan2
- CDK14 | c.1397A>T p.N466I (on ENST00000380050 / NM_001287135.2; = p.N448I on NM_012395.3) | Missense Mutation (SNP) | VAF 60/260 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.276); catalogued as rs1403771836; called by muse, mutect2, varscan2
- CDX2 | c.788C>G p.P263R | Missense Mutation (SNP) | VAF 152/811 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.067); catalogued as COSV66829872; called by muse, mutect2, varscan2
- CFAP57 | c.2275G>A p.D759N | Missense Mutation (SNP) | VAF 48/246 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1382475095; called by muse, mutect2, varscan2
- CHI3L1 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 262/456 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1558148062; called by muse, mutect2, varscan2
- CHRNG | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 76/295 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.544); catalogued as rs763468045; called by muse, mutect2, varscan2
- CILP2 | c.2252C>T p.P751L | Missense Mutation (SNP) | VAF 149/655 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as rs1312774460, COSV52272416; called by muse, mutect2, varscan2
- CNTN4 | c.1330G>A p.G444R | Missense Mutation (SNP) | VAF 47/286 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs762132167; called by muse, mutect2, varscan2
- CNTNAP2 | c.1384C>T p.R462C | Missense Mutation (SNP) | VAF 69/315 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs769071764, COSV62144657; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP5 | c.3907G>A p.E1303K | Missense Mutation (SNP) | VAF 73/246 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV70493883; called by muse, mutect2, varscan2
- COL4A3 | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 86/337 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67412851; called by muse, mutect2, varscan2
- COL4A4 | c.2604G>A p.M868I | Missense Mutation (SNP) | VAF 116/463 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.212); catalogued as COSV61630422; called by muse, varscan2
- COL4A4 | c.1706G>A p.G569E | Missense Mutation (SNP) | VAF 70/301 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61635131; called by muse, mutect2, varscan2
- COL6A6 | c.4219G>A p.G1407R | Missense Mutation (SNP) | VAF 83/356 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757998675; called by muse, mutect2, varscan2
- CPXM1 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 95/394 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1279634742; called by muse, mutect2, varscan2
- CRISP1 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 73/263 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.035); catalogued as rs866278869, COSV59995747; called by muse, mutect2, varscan2
- CSMD3 | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 53/304 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.325); catalogued as rs1314588305; called by muse, mutect2, varscan2
- CTNND2 | c.3502G>A p.D1168N | Missense Mutation (SNP) | VAF 100/492 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs756966820, COSV58908222; called by muse, mutect2, varscan2
- CUZD1 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 80/255 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.231); catalogued as rs866395304, COSV59028195; called by muse, mutect2, varscan2
- CWC22 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 46/260 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99843910; called by muse, mutect2, varscan2
- CYP2C9 | c.416G>A p.R139K | Missense Mutation (SNP) | VAF 124/444 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.078); catalogued as COSV53248976; called by muse, mutect2, varscan2
- CYP4F11 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 100/429 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.424); catalogued as COSV56125495; called by muse, mutect2, varscan2
- DCDC2 | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 67/477 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV101016610; called by muse, mutect2, varscan2
- DCLK3 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 90/408 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.011); catalogued as COSV69363204; called by muse, varscan2
- DMBT1 | c.2948C>T p.S983L (on ENST00000338354 / NM_001377530.1; = p.S484L on NM_004406.3) | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.728); catalogued as rs368577187; called by muse, mutect2, varscan2
- DMBT1 | c.5584G>A p.E1862K (on ENST00000338354 / NM_001377530.1; = p.E1105K on NM_004406.3) | Missense Mutation (SNP) | VAF 82/268 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as rs1045906158, COSV57534249; called by muse, mutect2, varscan2
- DNAH17 | c.3586G>A p.E1196K | Missense Mutation (SNP) | VAF 83/536 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as rs373729196, COSV67750417; called by muse, mutect2, varscan2
- DNAH6 | c.9185C>T p.S3062L | Missense Mutation (SNP) | VAF 89/387 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52851883; called by muse, mutect2, varscan2
- DNAH7 | c.10445G>A p.G3482E | Missense Mutation (SNP) | VAF 106/459 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56785294; called by muse, mutect2, varscan2
- DNAH7 | c.9457G>A p.E3153K | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV56784664; called by muse, mutect2, varscan2
- DPP10 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 59/300 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV59734695; called by muse, mutect2, varscan2
- DPYSL5 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 115/549 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs866373727, COSV56512143; called by muse, mutect2, varscan2
- DRD5 | c.971G>A p.G324E | Missense Mutation (SNP) | VAF 93/309 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.339); catalogued as COSV58576709; called by muse, mutect2, varscan2
- DSCAM | c.5761G>A p.D1921N | Missense Mutation (SNP) | VAF 88/384 reads (23%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.075); catalogued as COSV101261048; called by muse, mutect2, varscan2
- DVL1 | c.1924C>T p.P642S (on ENST00000378888 / NM_001330311.2; = p.P617S on NM_004421.3) | Missense Mutation (SNP) | VAF 137/534 reads (26%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs1410041869; called by mutect2, varscan2
- EDAR | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 91/389 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as rs910833939; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 61/322 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.25); catalogued as rs1349161709; called by muse, mutect2, varscan2
- EPHA8 | c.2024A>T p.E675V | Missense Mutation (SNP) | VAF 113/524 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51270353; called by muse, mutect2, varscan2
- EPPK1 | c.3095C>T p.P1032L | Missense Mutation (SNP) | VAF 124/573 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV101599877; called by muse, mutect2, varscan2
- ERC2 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 49/239 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs865915320, COSV99886730; called by muse, mutect2, varscan2
- EYA2 | c.719G>A p.R240K | Missense Mutation (SNP) | VAF 114/480 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.605); catalogued as COSV57943984; called by muse, mutect2, varscan2
- F3 | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 60/204 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866686212, COSV61845191; called by muse, mutect2, varscan2
- FAM189B | c.1700C>T p.S567L | Missense Mutation (SNP) | VAF 172/843 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs141156411, COSV100516531; called by muse, varscan2
- FAM237A | c.434G>A p.R145K | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.034); catalogued as COSV71513349; called by muse, mutect2, varscan2
- FAM50B | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 100/708 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.596); catalogued as rs1435667204; called by muse, mutect2, varscan2
- FARSA | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 78/394 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765172401, COSV53367504; called by muse, mutect2
- FER1L6 | c.5270C>T p.S1757F | Missense Mutation (SNP) | VAF 60/313 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.027); catalogued as rs763702847, COSV67549091; called by muse, mutect2, varscan2
- FGD5 | c.3193G>A p.D1065N | Missense Mutation (SNP) | VAF 90/319 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs528396278, COSV53240820; called by muse, mutect2, varscan2
- FLG | c.11578G>A p.G3860R | Missense Mutation (SNP) | VAF 104/533 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as rs1244741181; called by muse, mutect2, varscan2
- FLT1 | c.1987C>T p.L663F | Missense Mutation (SNP) | VAF 128/368 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1418663249; called by muse, mutect2, varscan2
- FMNL2 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 67/332 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56498872; called by muse, mutect2, varscan2
- FOLH1 | c.1848G>A p.M616I | Missense Mutation (SNP) | VAF 68/225 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV57045256; called by muse, mutect2, varscan2
- FOXH1 | c.997G>A p.G333R | Missense Mutation (SNP) | VAF 132/768 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as COSV100023907; called by muse, mutect2, varscan2
- FRAS1 | c.4022C>T p.P1341L | Missense Mutation (SNP) | VAF 179/466 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.287); catalogued as COSV99353211; called by muse, mutect2, varscan2
- FREM1 | c.5848C>T p.H1950Y | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1454928565; called by muse, mutect2, varscan2
- FREM3 | c.6206G>A p.R2069Q | Missense Mutation (SNP) | VAF 75/331 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.104); catalogued as rs575349973, COSV61680487; called by muse, mutect2, varscan2
- GALNT15 | c.1855C>T p.P619S | Missense Mutation (SNP) | VAF 111/409 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.037); catalogued as COSV60217264; called by muse, mutect2, varscan2
- GGT5 | c.1724C>T p.S575L | Missense Mutation (SNP) | VAF 110/517 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs752810876, COSV54068576; called by muse, mutect2, varscan2
- GPR142 | c.1276C>T p.R426* | Nonsense Mutation (SNP) | VAF 174/616 reads (28%) | catalogued as rs201061750; called by muse, mutect2, varscan2
- GPR151 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 114/508 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57034685; called by muse, mutect2, varscan2
- GPRC6A | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 58/256 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV59953750; called by muse, mutect2, varscan2
- GPX6 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 99/646 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs761502681; called by muse, mutect2, varscan2
- GRM5 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 59/234 reads (25%) | SIFT tolerated, low confidence (0.43); PolyPhen possibly damaging (0.838); catalogued as COSV59587970; called by muse, mutect2, varscan2
- GRM7 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 67/273 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100735523; called by muse, mutect2, varscan2
- HDGFL1 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 124/837 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as rs1158921448; called by muse, mutect2, varscan2
- HMCN1 | c.14353G>A p.D4785N | Missense Mutation (SNP) | VAF 96/503 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV99632148; called by muse, mutect2, varscan2
- HPS1 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 75/254 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as rs759798824, COSV57270714; called by muse, mutect2, varscan2
- HSD17B7 | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 51/273 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as rs747982937; called by muse, mutect2, varscan2
- HSPA12B | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 101/398 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs751778150; called by muse, mutect2, varscan2
- HYDIN | c.4897C>T p.L1633F | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765728604, COSV99992502; called by muse, mutect2, varscan2
- IGHA1 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 150/624 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as rs745626375; called by muse, mutect2, varscan2
- IGHM | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 87/314 reads (28%) | SIFT tolerated (0.23); catalogued as rs369884599; called by muse, mutect2, varscan2
- IGKV3-20 | c.119C>T p.T40I | Missense Mutation (SNP) | VAF 106/556 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as rs764799310; called by muse, mutect2, varscan2
- IGLL5 | c.518A>G p.K173R | Missense Mutation (SNP) | VAF 147/649 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.166); catalogued as COSV66533773; called by muse, mutect2, varscan2
- IL1RL1 | c.979C>T p.H327Y | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775650722; called by muse, mutect2, varscan2
- IL4R | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 92/475 reads (19%) | SIFT tolerated (0.82); PolyPhen benign (0.01); catalogued as rs1273255220, COSV50138641; called by muse, mutect2, varscan2
- ILF3 | c.1529C>T p.P510L | Missense Mutation (SNP) | VAF 82/353 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs1283238244; called by muse, mutect2, varscan2
- INPP5D | c.655G>A p.E219K (on ENST00000445964 / NM_001017915.3; = p.E218K on NM_005541.5) | Missense Mutation (SNP) | VAF 77/295 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.058); catalogued as COSV64036099; called by muse, mutect2, varscan2
- INPP5J | c.1695G>A p.M565I (on ENST00000331075 / NM_001284285.2; = p.M197I on NM_001002837.2) | Missense Mutation (SNP) | VAF 114/438 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); catalogued as rs1249299074; called by muse, mutect2, varscan2
- INSR | c.2354C>T p.S785L | Missense Mutation (SNP) | VAF 111/478 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as rs145643501; called by muse, mutect2, varscan2
- INSYN2A | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 115/384 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.371); catalogued as rs143223796; called by muse, mutect2, varscan2
- INTS13 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 57/257 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99677579; called by muse, mutect2, varscan2
- IQCH | c.3024G>A p.M1008I | Missense Mutation (SNP) | VAF 73/348 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs745493481, COSV100246450; called by muse, mutect2, varscan2
- IRF2BP2 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 130/656 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.114); catalogued as COSV100784361; called by muse, mutect2, varscan2
- KBTBD8 | c.1559C>T p.S520F | Missense Mutation (SNP) | VAF 84/364 reads (23%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.548); catalogued as COSV55130997; called by muse, mutect2, varscan2
- KCNA4 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 102/471 reads (22%) | catalogued as COSV100069337; called by muse, mutect2, varscan2
- KCNG4 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 115/489 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100377145, COSV57582702; called by muse, mutect2, varscan2
- KCNJ15 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 118/436 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60812062; called by muse, mutect2, varscan2
- KCNQ3 | c.2324C>T p.S775F | Missense Mutation (SNP) | VAF 130/670 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV101196223, COSV66463807; called by muse, mutect2, varscan2
- KDR | c.3472G>A p.E1158K | Missense Mutation (SNP) | VAF 143/403 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55775864; called by muse, mutect2, varscan2
- KIF1A | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 79/433 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57503270; called by muse, mutect2, varscan2
- KIFAP3 | c.1151T>C p.V384A | Missense Mutation (SNP) | VAF 85/362 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs369373148; called by muse, mutect2, varscan2
- KLK7 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 72/272 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV58345012; called by muse, mutect2, varscan2
- KMT2B | c.6892C>T p.P2298S | Missense Mutation (SNP) | VAF 146/551 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs1352168510; called by muse, mutect2, varscan2
- KMT2E | c.3468G>A p.K1156= | Splice Region (SNP) | VAF 63/229 reads (28%) | catalogued as COSV99996788; called by muse, mutect2, varscan2
- KNDC1 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 70/231 reads (30%) | SIFT tolerated (0.83); PolyPhen benign (0.05); catalogued as COSV58841297; called by muse, mutect2, varscan2
- KRT26 | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as rs1323748792; called by muse, mutect2, varscan2
- KRT4 | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 98/430 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV53407006; called by muse, mutect2, varscan2
- LCE1C | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 114/703 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.553); catalogued as COSV64219019; called by muse, mutect2, varscan2
- LILRA1 | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 124/817 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765135169, COSV52185615; called by muse, varscan2
- LILRB5 | c.1447C>T p.R483W (on ENST00000449561 / NM_001081442.3; = p.R482W on NM_006840.5) | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs752859717, COSV60254171, COSV60255683; called by muse, mutect2, varscan2
- LMBR1 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV62223310; called by muse, mutect2, varscan2
- LPA | c.3215G>A p.G1072E | Missense Mutation (SNP) | VAF 65/376 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60311532; called by muse, mutect2, varscan2
- LRP1 | c.9046G>A p.G3016S | Missense Mutation (SNP) | VAF 52/303 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.017); catalogued as rs749283705, COSV54503415; called by muse, mutect2, varscan2
- LRRC45 | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 86/519 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV60710315; called by muse, mutect2, varscan2
- LRRC66 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 108/531 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.057); catalogued as rs747530792; called by muse, mutect2, varscan2
- MACF1 | c.10013C>T p.P3338L | Missense Mutation (SNP) | VAF 82/374 reads (22%) | catalogued as COSV57145336; called by muse, mutect2, varscan2
- MAGI1 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 95/442 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.069); catalogued as COSV58327154; called by muse, mutect2, varscan2
- MAGOHB | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 69/306 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs762002632, COSV100296222; called by muse, mutect2, varscan2
- MAN1A1 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 46/247 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV63782179; called by muse, mutect2, varscan2
- MAP2 | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 122/479 reads (25%) | catalogued as COSV52306755; called by muse, mutect2, varscan2
- MAPK15 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 150/620 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as rs370712189; called by muse, mutect2, varscan2
- MBD1 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 54/290 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.909); catalogued as rs1182748371; called by muse, mutect2, varscan2
- MCHR2 | c.13C>T p.H5Y | Missense Mutation (SNP) | VAF 50/262 reads (19%) | SIFT tolerated (0.98); PolyPhen benign (0.018); catalogued as rs1233222158, COSV56001920; called by muse, mutect2, varscan2
- MDGA2 | c.958C>T p.P320S (on ENST00000399232 / NM_001113498.2; = p.P22S on NM_182830.4) | Missense Mutation (SNP) | VAF 52/290 reads (18%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.923); catalogued as COSV62081244; called by muse, mutect2, varscan2
- MDGA2 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 62/282 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV62080879; called by muse, mutect2, varscan2
- ME1 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 75/284 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.154); catalogued as rs1198046791; called by muse, varscan2
- MRO | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 84/385 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56496060; called by muse, mutect2, varscan2
- MROH2B | c.3031G>A p.E1011K | Missense Mutation (SNP) | VAF 99/404 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV68181475; called by muse, mutect2, varscan2
- MTHFR | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 76/419 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs745779146; called by muse, mutect2, varscan2
- MUC16 | c.7036G>A p.E2346K | Missense Mutation (SNP) | VAF 59/296 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as rs1211609182, COSV67444208, COSV67464032; called by muse, mutect2, varscan2
- MUC16 | c.2809C>T p.P937S | Missense Mutation (SNP) | VAF 75/314 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV67454362; called by muse, mutect2, varscan2
- MUC2 | c.2188G>A p.G730R | Missense Mutation (SNP) | VAF 58/328 reads (18%) | SIFT tolerated (0.32); catalogued as rs1335177280; called by muse, mutect2, varscan2
- MX1 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 81/348 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.166); catalogued as rs368516551; called by muse, mutect2, varscan2
- NABP1 | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 66/340 reads (19%) | catalogued as rs762881375; called by muse, mutect2, varscan2
- NCKAP5 | c.5557G>A p.E1853K | Missense Mutation (SNP) | VAF 70/367 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.234); catalogued as COSV58437572; called by muse, mutect2, varscan2
- NEUROD1 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 95/403 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54551442; called by muse, mutect2, varscan2
- NEXMIF | c.1961C>T p.S654L | Missense Mutation (SNP) | VAF 74/185 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs267606511, COSV50045459, COSV99280638; called by muse, mutect2, varscan2
- NLRP5 | c.1537C>T p.R513* | Nonsense Mutation (SNP) | VAF 104/429 reads (24%) | catalogued as rs1345175754, COSV66762161; called by muse, mutect2, varscan2
- NMS | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 111/397 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.022); catalogued as COSV65258334; called by muse, mutect2, varscan2
- NOMO2 | c.1772T>C p.M591T | Missense Mutation (SNP) | VAF 52/453 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.045); catalogued as COSV100395581; called by muse, mutect2, varscan2
- NPAP1 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 90/429 reads (21%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.801); catalogued as rs868115699, COSV61504054; called by muse, mutect2, varscan2
- NPY2R | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 92/440 reads (21%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs1318700369, COSV61528421; called by muse, mutect2, varscan2
- NR5A2 | c.629C>T p.S210F (on ENST00000367362 / NM_205860.3; = p.S164F on NM_003822.5) | Missense Mutation (SNP) | VAF 107/612 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.438); catalogued as rs1280566946; called by muse, mutect2, varscan2
- NXPH3 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 106/417 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); catalogued as rs762101820, COSV60871904; called by muse, mutect2, varscan2
- OBSCN | c.6697G>A p.G2233R | Missense Mutation (SNP) | VAF 313/595 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99478311; called by muse, mutect2, varscan2
- OR10H4 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 78/293 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.044); catalogued as COSV59062957; called by muse, mutect2, varscan2
- OR14A16 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 64/379 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.411); catalogued as COSV100713646; called by muse, mutect2, varscan2
- OR1J1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 87/276 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV52239261; called by muse, mutect2, varscan2
- OR1J4 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 77/328 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); catalogued as COSV61589697; called by muse, mutect2, varscan2
- OR2C1 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 111/463 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1161658977, COSV59241583; called by muse, mutect2, varscan2
- OR4K13 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 97/496 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV100237631, COSV59860273; called by muse, mutect2, varscan2
- OR4K15 | c.701C>T p.S234F (on ENST00000305051; = p.S210F on NM_001005486.1) | Missense Mutation (SNP) | VAF 76/322 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV59300274; called by muse, mutect2, varscan2
- OR4Q2 | c.525+1G>A | Missense Mutation (SNP) | VAF 58/300 reads (19%) | catalogued as rs895174410; called by muse, mutect2, varscan2
- OR51A7 | c.406C>T p.L136F | Missense Mutation (SNP) | VAF 104/427 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1486123534; called by muse, mutect2, varscan2
- OR51M1 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 107/516 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as rs866442558, COSV60785779; called by muse, mutect2
- OR52L1 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 120/451 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs867894367, COSV59985811; called by muse, mutect2, varscan2
- OR5P3 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 127/442 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV60429983; called by muse, mutect2, varscan2
- OR6N1 | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 342/562 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as COSV100625282, COSV100625307; called by muse, mutect2, varscan2
- OR6T1 | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 107/421 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs76969055, COSV58305873, COSV58308619; called by muse, mutect2, varscan2
- OR8D1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 77/355 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV63441764; called by muse, mutect2, varscan2
- OR8D2 | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 107/425 reads (25%) | catalogued as COSV62488191; called by muse, mutect2, varscan2
- OTOF | c.3082G>A p.D1028N (on ENST00000272371 / NM_194248.3; = p.D281N on NM_004802.4) | Missense Mutation (SNP) | VAF 71/316 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs990441718, COSV99045318; called by muse, mutect2, varscan2
- PAK5 | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 110/426 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs562732119, COSV62020766; called by muse, varscan2
- PCDHGB1 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 137/478 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as rs776868264; called by muse, mutect2, varscan2
- PCDHGB4 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 44/293 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV99541914; called by muse, mutect2, varscan2
- PCNX2 | c.3853C>T p.H1285Y | Missense Mutation (SNP) | VAF 176/459 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV50815782; called by muse, mutect2, varscan2
- PDGFD | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 57/264 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV56368858, COSV56380199; called by muse, mutect2, varscan2
- PDGFRA | c.2486G>A p.G829E | Missense Mutation (SNP) | VAF 101/464 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV57268333, COSV99955745; called by muse, mutect2, varscan2
- PIK3C2G | c.2779G>A p.G927R (on ENST00000676171; = p.G886R on NM_004570.5) | Missense Mutation (SNP) | VAF 54/251 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749548432; called by muse, mutect2, varscan2
- PKHD1L1 | c.10456G>A p.D3486N | Missense Mutation (SNP) | VAF 60/360 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.857); catalogued as COSV65742781; called by muse, mutect2, varscan2
- PKP4 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 124/525 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as rs755121004; called by muse, mutect2, varscan2
- PLIN5 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 93/389 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs745792972; called by muse, mutect2, varscan2
- PLPP3 | c.262C>T p.L88F | Missense Mutation (SNP) | VAF 69/344 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64840147; called by muse, mutect2, varscan2
- PLXNA4 | c.1831C>T p.Q611* | Nonsense Mutation (SNP) | VAF 82/398 reads (21%) | catalogued as COSV100324538; called by muse, mutect2, varscan2
- PLXND1 | c.1613C>T p.S538F | Missense Mutation (SNP) | VAF 53/224 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1311024180; called by muse, mutect2, varscan2
- POM121L2 | c.1694C>T p.S565F | Missense Mutation (SNP) | VAF 91/592 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as rs750806659; called by muse, mutect2, varscan2
- POMT2 | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 63/280 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.795); catalogued as rs1421956619; called by muse, mutect2, varscan2
- PPFIA2 | c.2372C>T p.S791F | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV61019849; called by muse, mutect2, varscan2
- PPM1B | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 79/322 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.526); catalogued as rs765714663; called by muse, mutect2, varscan2
- PPM1D | c.1372C>T p.R458* | Nonsense Mutation (SNP) | VAF 98/609 reads (16%) | catalogued as rs773389405, CM137522, COSV59954743; called by muse, mutect2, varscan2
- PPP4R4 | c.1743G>A p.W581* | Nonsense Mutation (SNP) | VAF 48/226 reads (21%) | catalogued as COSV100428917; called by muse, mutect2, varscan2
- PRB4 | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 74/617 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.688); catalogued as COSV54400048; called by muse, varscan2
- PRDM16 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 89/350 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs576922307, COSV99577007; called by muse, mutect2, varscan2
- PRKCB | c.1655C>T p.S552F | Missense Mutation (SNP) | VAF 73/296 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57788429; called by muse, mutect2, varscan2
- PTBP2 | c.1240C>T p.R414C (on ENST00000426398 / NM_001300986.2; = p.R406C on NM_021190.4) | Missense Mutation (SNP) | VAF 61/231 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV64623232; called by muse, mutect2, varscan2
- PTPRB | c.4978C>T p.R1660C | Missense Mutation (SNP) | VAF 95/395 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs868318095, COSV54231634; called by muse, mutect2, varscan2
- PWWP3B | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.093); catalogued as COSV61801580; called by muse, mutect2, varscan2
- RAB11FIP1 | c.760C>A p.Q254K | Missense Mutation (SNP) | VAF 118/486 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV54759732; called by muse, mutect2, varscan2
- RBFOX1 | c.763G>A p.G255S | Missense Mutation (SNP) | VAF 82/382 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.913); catalogued as rs1568300140; called by muse, varscan2
- RBM26 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 124/415 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1307109321, COSV99936756; called by muse, mutect2, varscan2
- RBM33 | c.1952C>T p.P651L | Missense Mutation (SNP) | VAF 76/440 reads (17%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as rs1477956603, COSV56635280; called by muse, varscan2
- RBMY1E | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 89/394 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.785); catalogued as rs748995910; called by muse, mutect2, varscan2
- RCBTB1 | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 181/491 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs146138087; called by muse, mutect2, varscan2
- RFX6 | c.2080C>T p.H694Y | Missense Mutation (SNP) | VAF 97/407 reads (24%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.052); catalogued as COSV60588785; called by muse, mutect2, varscan2
- RGS6 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 60/331 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.862); catalogued as rs757454073; called by muse, mutect2, varscan2
- RGS7 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 198/382 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755007339, COSV58530073, COSV58530443; called by muse, mutect2, varscan2
- RGSL1 | c.2315C>T p.S772L | Missense Mutation (SNP) | VAF 65/350 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1458567397, COSV54259251; called by muse, mutect2, varscan2
- RIMBP2 | c.2545C>T p.P849S | Missense Mutation (SNP) | VAF 72/373 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV55464658; called by muse, mutect2, varscan2
- RNASE10 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 118/477 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.105); catalogued as rs1176902119; called by muse, mutect2, varscan2
- ROPN1L | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.079); catalogued as COSV56873402; called by muse, mutect2, varscan2
- RPTN | c.2042C>T p.S681L | Missense Mutation (SNP) | VAF 334/606 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV60168196; called by muse, mutect2, varscan2
- RRAD | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 86/350 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs761072134, COSV55339063; called by muse, mutect2, varscan2
- RTL3 | c.920G>A p.S307N | Missense Mutation (SNP) | VAF 123/269 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1336295598; called by muse, mutect2, varscan2
- RUFY2 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 72/222 reads (32%) | catalogued as rs768777155, COSV100700084; called by muse, mutect2, varscan2
- RYR1 | c.5464G>A p.G1822S | Missense Mutation (SNP) | VAF 116/496 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.588); catalogued as rs1169294876, COSV100614822, COSV62113655; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR1 | c.13565C>T p.P4522L | Missense Mutation (SNP) | VAF 120/499 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.098); catalogued as rs145167688, COSV100617189; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SBK2 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 151/660 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1349790004; called by muse, mutect2, varscan2
- SCAF8 | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63200244; called by muse, mutect2, varscan2
- SCN10A | c.5582C>T p.A1861V | Missense Mutation (SNP) | VAF 109/454 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1559405676; called by muse, mutect2, varscan2
- SDC1 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 97/483 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54341147; called by muse, mutect2, varscan2
- SDK2 | c.4835C>T p.P1612L | Missense Mutation (SNP) | VAF 213/715 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV66197417; called by muse, mutect2, varscan2
- SEZ6 | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 89/413 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.63); catalogued as rs543072698; called by muse, mutect2, varscan2
- SHROOM3 | c.5642G>T p.R1881M | Missense Mutation (SNP) | VAF 59/266 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV56030203; called by muse, mutect2, varscan2
- SLA | c.463G>A p.D155N (on ENST00000338087 / NM_001045556.3; = p.D195N on NM_006748.4) | Missense Mutation (SNP) | VAF 69/409 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV55064761; called by muse, mutect2, varscan2
- SLC15A1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 62/193 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs558276843, COSV64712471; called by muse, mutect2, varscan2
- SLC16A10 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 50/240 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs774929205, COSV100920788, COSV64354112; called by muse, mutect2, varscan2
- SLC1A2 | c.1433G>A p.R478K | Missense Mutation (SNP) | VAF 76/303 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53523614; called by muse, mutect2, varscan2
- SLC22A8 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 138/511 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs766443125, COSV60324647; called by muse, mutect2, varscan2
- SLC26A8 | c.2114G>A p.G705E | Missense Mutation (SNP) | VAF 80/309 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV62885547; called by muse, mutect2, varscan2
- SLC35G6 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 123/396 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs768682795; called by muse, mutect2, varscan2
- SLC37A3 | c.1337C>T p.S446F (on ENST00000326232 / NM_001363375.1; = p.V345= on NM_032295.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/298 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV58265400; called by muse, mutect2, varscan2
- SLC43A1 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 50/265 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs775770599; called by muse, mutect2, varscan2
- SLC7A13 | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 101/528 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867805359, COSV52534817, COSV99879296; called by muse, mutect2, varscan2
- SLC9A2 | c.2417G>A p.R806Q | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.124); catalogued as COSV52133460, COSV52134343; called by muse, mutect2, varscan2
- SLCO1B1 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as COSV57011275; called by muse, mutect2, varscan2
- SLCO6A1 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 59/258 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV65811703; called by muse, mutect2, varscan2
- SLFN11 | c.184C>T p.R62* | Nonsense Mutation (SNP) | VAF 123/506 reads (24%) | catalogued as rs758613276, COSV57699590; called by muse, mutect2
- SLIT3 | c.4093G>A p.D1365N | Missense Mutation (SNP) | VAF 86/419 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs770091737, COSV60594584; called by muse, mutect2, varscan2
- SLITRK6 | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 180/473 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV101233277; called by muse, mutect2, varscan2
- SNX33 | c.656G>C p.R219P | Missense Mutation (SNP) | VAF 93/455 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.094); catalogued as COSV100145767; called by muse, mutect2, varscan2
- SORL1 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 73/316 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372363423; called by muse, mutect2, varscan2
- SP140L | c.232C>T p.L78F | Missense Mutation (SNP) | VAF 58/254 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs540920855, COSV54744561; called by muse, mutect2, varscan2
- SPEG | c.3676C>T p.H1226Y | Missense Mutation (SNP) | VAF 65/362 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as rs1162592760; called by muse, mutect2, varscan2
- SPHKAP | c.2071G>A p.D691N | Missense Mutation (SNP) | VAF 96/413 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs749269337, COSV60871065, COSV60884194; called by muse, mutect2, varscan2
- SRRM2 | c.5222C>T p.S1741F | Missense Mutation (SNP) | VAF 80/364 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV57083264; called by muse, mutect2, varscan2
- SRSF6 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 82/345 reads (24%) | catalogued as COSV99719758; called by muse, mutect2, varscan2
- STK31 | c.2950G>A p.E984K | Missense Mutation (SNP) | VAF 81/388 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.15); catalogued as rs763457395, COSV63456841; called by muse, mutect2, varscan2
- STON2 | c.872C>T p.T291I (on ENST00000649389 / NM_001366849.2; = p.T234I on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 125/472 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs776784409, COSV104388780; called by muse, mutect2, varscan2
- SULT2A1 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 121/436 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs763687131, COSV55764410; called by muse, mutect2, varscan2
- SVOPL | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 75/382 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as rs757982706, COSV55989424; called by muse, mutect2, varscan2
- SWT1 | c.2323C>T p.Q775* | Nonsense Mutation (SNP) | VAF 29/235 reads (12%) | catalogued as COSV100833130; called by muse, mutect2, varscan2
- SYN3 | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 88/384 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as rs752060058, COSV100249870; called by muse, mutect2, varscan2
- TACC2 | c.7519G>A p.E2507K (on ENST00000334433; = p.E585K on NM_006997.4) | Missense Mutation (SNP) | VAF 69/213 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV53276716; called by muse, mutect2, varscan2
- TCEA3 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 57/316 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs575626010, COSV101004600; called by muse, mutect2, varscan2
- TENT5C | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 101/598 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs779467652, COSV101033189, COSV65616833; called by muse, mutect2, varscan2
- TEX15 | c.4694C>T p.S1565F (on ENST00000256246; = p.S1948F on NM_001350162.2) | Missense Mutation (SNP) | VAF 73/329 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.068); catalogued as COSV56348113; called by muse, mutect2, varscan2
- TFAP2C | c.379C>T p.H127Y | Missense Mutation (SNP) | VAF 141/566 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.412); catalogued as rs1335692959; called by muse, mutect2, varscan2
- TGM1 | c.2327C>T p.S776F | Missense Mutation (SNP) | VAF 108/387 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV99253344; called by muse, mutect2, varscan2
- TGM7 | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 46/213 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs185269396, COSV101476827, COSV71772819; called by muse, mutect2, varscan2
- THAP10 | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 115/482 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.496); catalogued as rs924935418; called by muse, mutect2, varscan2
- THBS1 | c.3058G>A p.D1020N | Missense Mutation (SNP) | VAF 99/447 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767595971; called by muse, mutect2, varscan2
- THSD7B | c.4340G>A p.R1447Q (on ENST00000272643; = p.R1445Q on NM_001316349.2) | Missense Mutation (SNP) | VAF 90/403 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs267598902, COSV55651965; called by muse, mutect2, varscan2
- TMEM225 | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 78/309 reads (25%) | catalogued as COSV100902828; called by muse, mutect2, varscan2
- TNFSF8 | c.442C>T p.L148F | Missense Mutation (SNP) | VAF 84/261 reads (32%) | SIFT tolerated (0.83); PolyPhen benign (0.012); catalogued as COSV56342170; called by muse, mutect2, varscan2
- TNN | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 91/559 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs776834667, COSV53426449, COSV99513441; called by muse, mutect2, varscan2
- TONSL | c.2261G>A p.R754Q | Missense Mutation (SNP) | VAF 260/624 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs753231160, COSV68047863; called by muse, varscan2
- TOPAZ1 | c.3007G>A p.E1003K | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59064734; called by muse, mutect2, varscan2
- TP73 | c.1579G>A p.D527N | Missense Mutation (SNP) | VAF 76/291 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as rs1242463021; called by muse, mutect2, varscan2
- TRAV22 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 80/276 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as rs267603936; called by muse, mutect2, varscan2
- TRIM43B | c.485G>A p.R162K | Missense Mutation (SNP) | VAF 33/217 reads (15%) | SIFT tolerated (0.94); PolyPhen benign (0.005); catalogued as COSV71108736; called by muse, mutect2, varscan2
- TSKS | c.1712G>A p.G571E | Missense Mutation (SNP) | VAF 73/463 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.79); catalogued as rs868763430, COSV55876225; called by muse, mutect2, varscan2
- TTN | c.7695G>A p.W2565* (on ENST00000591111; = p.W2519* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 94/375 reads (25%) | catalogued as COSV100610632, COSV100629571; called by muse, mutect2, varscan2
- TULP4 | c.3838C>T p.P1280S | Missense Mutation (SNP) | VAF 109/541 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.998); catalogued as COSV65581794; called by muse, mutect2, varscan2
- UBQLN3 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 117/460 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV61163552; called by muse, mutect2, varscan2
- UBR1 | c.4862G>A p.R1621Q | Missense Mutation (SNP) | VAF 68/337 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs752483268; called by muse, mutect2, varscan2
- UGT1A6 | c.1370C>T p.A457V | Missense Mutation (SNP) | VAF 108/500 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373052727; called by muse, mutect2, varscan2
- UGT2B10 | c.868-1G>A p.X290_splice | Splice Site (SNP) | VAF 113/269 reads (42%) | catalogued as rs782107811, COSV99607792; called by muse, mutect2, varscan2
- UNC13C | c.2110G>A p.D704N | Missense Mutation (SNP) | VAF 82/429 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV52928640; called by muse, mutect2, varscan2
- UNC80 | c.8879C>T p.S2960L | Missense Mutation (SNP) | VAF 65/262 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.113); catalogued as rs1217680040, COSV99778319; called by muse, mutect2, varscan2
- USP31 | c.3266C>T p.S1089F | Missense Mutation (SNP) | VAF 131/492 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1192876249, COSV54854238; called by muse, mutect2, varscan2
- VPS13D | c.9257C>T p.S3086L | Missense Mutation (SNP) | VAF 99/421 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as rs753255422, COSV50640979; called by muse, mutect2, varscan2
- YBX3 | c.763C>T p.H255Y | Missense Mutation (SNP) | VAF 59/237 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.3); catalogued as rs776931399; called by muse, varscan2
- ZDBF2 | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 90/417 reads (22%) | catalogued as rs772203809, COSV100985238; called by muse, mutect2, varscan2
- ZNF208 | c.1723C>T p.H575Y | Missense Mutation (SNP) | VAF 52/274 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.486); catalogued as rs1163866186, COSV68109181, COSV68111424; called by muse, mutect2, varscan2
- ZNF407 | c.2923C>T p.H975Y | Missense Mutation (SNP) | VAF 94/382 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.25); catalogued as rs1309429589, COSV55254627; called by muse, mutect2, varscan2
- ZNF429 | c.1507C>T p.H503Y | Missense Mutation (SNP) | VAF 71/298 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as rs779948744, COSV61918229; called by muse, mutect2, varscan2
- ZNF483 | c.1259C>T p.S420L | Missense Mutation (SNP) | VAF 90/262 reads (34%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV58516699; called by muse, mutect2, varscan2
- ZNF541 | c.1783G>A p.G595R | Missense Mutation (SNP) | VAF 116/555 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs879355467; called by muse, mutect2, varscan2
- ZNF664 | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 101/441 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as rs767125869; called by muse, mutect2, varscan2
- ZNF665 | c.457C>T p.R153C (on ENST00000600412; = p.R218C on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/379 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.151); catalogued as rs574751382, COSV67215170; called by muse, mutect2, varscan2
- ZNF677 | c.1100G>A p.R367K | Missense Mutation (SNP) | VAF 89/438 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.4); catalogued as rs1292360042, COSV61720215; called by muse, mutect2, varscan2
- ZNF679 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 90/363 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs1040679140; called by muse, mutect2, varscan2
- ZNF716 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 82/444 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.024); catalogued as rs782593726, COSV70779643, COSV70782140; called by muse, mutect2, varscan2
- ZNF90 | c.583C>T p.H195Y | Missense Mutation (SNP) | VAF 89/350 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.925); catalogued as rs1555705932, COSV101367262; called by muse, mutect2, varscan2
- ABCG1 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 107/431 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AC021072.1 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 115/473 reads (24%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM32 | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 77/333 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ADCY10 | c.4261G>A p.G1421R | Missense Mutation (SNP) | VAF 227/430 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ADGRB1 | c.4258C>T p.P1420S | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ADGRL4 | c.329A>G p.N110S | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGBL2 | c.1525G>A p.G509R | Missense Mutation (SNP) | VAF 89/388 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHNAK2 | c.9152T>A p.V3051D | Missense Mutation (SNP) | VAF 130/572 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- AMOTL2 | c.734G>A p.R245K | Missense Mutation (SNP) | VAF 69/260 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- AMPD1 | c.2099T>G p.I700S | Missense Mutation (SNP) | VAF 66/408 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- AMY1C | c.886G>A p.G296R | Missense Mutation (SNP) | VAF 31/368 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANKRD35 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 74/462 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- ANKRD9 | c.391_402dup p.R131_R134dup | In Frame Ins (INS) | VAF 107/534 reads (20%) | called by mutect2, varscan2
- ANKS1B | c.2528G>A p.G843E (on ENST00000547776 / NM_152788.4; = p.G69E on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/245 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AQP9 | c.735G>A p.W245* | Nonsense Mutation (SNP) | VAF 71/338 reads (21%) | called by muse, mutect2, varscan2
- ARMH1 | c.1129-1G>A p.X377_splice | Splice Site (SNP) | VAF 69/304 reads (23%) | called by muse, mutect2, varscan2
- ARMT1 | c.743T>A p.V248E | Missense Mutation (SNP) | VAF 68/348 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ASAH2 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 60/226 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ASPG | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 64/271 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- ATMIN | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- ATP6V0D2 | c.856G>A p.G286R | Missense Mutation (SNP) | VAF 97/471 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ATP7B | c.2399C>T p.A800V | Missense Mutation (SNP) | VAF 76/401 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATRN | c.3944A>G p.Q1315R | Missense Mutation (SNP) | VAF 74/309 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- BCAN | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 186/517 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- BCLAF1 | c.839G>A p.G280E | Missense Mutation (SNP) | VAF 38/249 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- C3orf20 | c.1754G>A p.R585K | Missense Mutation (SNP) | VAF 91/351 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CA9 | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 123/540 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- CACNA1I | c.6559G>A p.D2187N | Missense Mutation (SNP) | VAF 140/600 reads (23%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAGE1 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 53/435 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- CAPN8 | c.1933G>C p.V645L | Missense Mutation (SNP) | VAF 69/451 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- CARD6 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 88/367 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CARMIL1 | c.950T>A p.L317* | Nonsense Mutation (SNP) | VAF 53/346 reads (15%) | called by muse, mutect2, varscan2
- CCDC114 | c.624G>A p.M208I | Missense Mutation (SNP) | VAF 119/519 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC148 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 108/466 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- CCDC8 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 118/531 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- CCL16 | c.195C>T p.I65= | Splice Region (SNP) | VAF 69/330 reads (21%) | called by muse, mutect2, varscan2
- CCNF | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 72/398 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CD163L1 | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 84/354 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDCP2 | c.1491G>A p.M497I | Missense Mutation (SNP) | VAF 125/518 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP46 | c.7599G>A p.W2533* | Nonsense Mutation (SNP) | VAF 64/239 reads (27%) | called by muse, mutect2, varscan2
- CFAP47 | c.6772C>T p.P2258S | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CFHR3 | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 173/342 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- CHD5 | c.2989T>C p.Y997H | Missense Mutation (SNP) | VAF 60/346 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CHIT1 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 270/452 reads (60%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLASP1 | c.3796C>T p.P1266S | Missense Mutation (SNP) | VAF 82/344 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- CLEC4F | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 54/246 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLRN1 | c.456G>A p.M152I (on ENST00000327047 / NM_174878.3; = p.M76I on NM_052995.2) | Missense Mutation (SNP) | VAF 74/267 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- CNBD1 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 50/320 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by mutect2, varscan2
- CNTN5 | c.2948G>A p.W983* | Nonsense Mutation (SNP) | VAF 91/363 reads (25%) | called by muse, mutect2, varscan2
- COL14A1 | c.692A>T p.K231I | Missense Mutation (SNP) | VAF 144/352 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A2 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 97/371 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A4 | c.1927C>T p.H643Y | Missense Mutation (SNP) | VAF 106/532 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CPVL | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 101/427 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- CREBRF | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 59/270 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- CROCC2 | c.3968G>A p.G1323D | Missense Mutation (SNP) | VAF 70/349 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CSMD2 | c.3442G>A p.G1148R | Missense Mutation (SNP) | VAF 80/332 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CTNNA3 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 94/287 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CTNND2 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 63/339 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CUX1 | c.3542C>T p.P1181L | Missense Mutation (SNP) | VAF 99/439 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYSTM1 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 95/432 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DAPK1 | c.1123C>A p.P375T | Missense Mutation (SNP) | VAF 55/211 reads (26%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- DDX43 | c.1925G>A p.G642E | Missense Mutation (SNP) | VAF 55/254 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- DGKZ | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 91/420 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DISP3 | c.3888T>G p.S1296R | Missense Mutation (SNP) | VAF 85/468 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH3 | c.6679A>C p.I2227L | Missense Mutation (SNP) | VAF 68/333 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- DNAH3 | c.3550G>A p.E1184K | Missense Mutation (SNP) | VAF 68/332 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- DNAH5 | c.6595C>T p.P2199S | Missense Mutation (SNP) | VAF 50/261 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- DNAI1 | c.816G>A p.Q272= | Splice Region (SNP) | VAF 62/256 reads (24%) | called by muse, mutect2, varscan2
- DNASE2B | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 65/272 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DPY19L4 | c.1874C>T p.S625F | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DRD5 | c.291G>A p.W97* | Nonsense Mutation (SNP) | VAF 12/442 reads (3%) | called by muse, mutect2
- DSEL | c.804G>A p.M268I | Missense Mutation (SNP) | VAF 106/475 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- DYSF | c.2704C>T p.P902S | Missense Mutation (SNP) | VAF 106/449 reads (24%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EEF2K | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 89/409 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- EFCAB8 | c.2219C>T p.P740L | Missense Mutation (SNP) | VAF 90/365 reads (25%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ELAVL4 | c.354G>A p.K118= | Splice Region (SNP) | VAF 50/202 reads (25%) | called by muse, varscan2
- ENC1 | c.1217C>T p.S406F | Missense Mutation (SNP) | VAF 91/419 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ENO4 | c.709A>T p.M237L (on ENST00000622726; = p.M236L on NM_001242699.2) | Missense Mutation (SNP) | VAF 107/372 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- EPHB4 | c.1241C>T p.S414F | Missense Mutation (SNP) | VAF 91/458 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- EPPK1 | c.4675G>A p.E1559K | Missense Mutation (SNP) | VAF 114/575 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ERC2 | c.1594G>A p.D532N | Missense Mutation (SNP) | VAF 96/410 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ETS2 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 69/294 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ETV4 | c.485T>G p.F162C | Missense Mutation (SNP) | VAF 123/539 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); called by muse, mutect2
- F13A1 | c.1415G>A p.G472E | Missense Mutation (SNP) | VAF 83/560 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FAM171A1 | c.2071A>T p.K691* | Nonsense Mutation (SNP) | VAF 181/445 reads (41%) | called by muse, mutect2, varscan2
- FAM186A | c.2776G>A p.E926K | Missense Mutation (SNP) | VAF 111/523 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- FAM47C | c.187C>T p.Q63* | Nonsense Mutation (SNP) | VAF 163/359 reads (45%) | called by muse, mutect2, varscan2
- FANCM | c.58del p.S20Lfs*51 | Frame Shift Del (DEL) | VAF 62/296 reads (21%) | called by mutect2, pindel*, varscan2
- FAT3 | c.11833C>T p.L3945F | Missense Mutation (SNP) | VAF 66/308 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FCRL5 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 68/443 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- FLG | c.4736G>A p.G1579E | Missense Mutation (SNP) | VAF 90/477 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- FNDC3B | c.2275G>A p.E759K | Missense Mutation (SNP) | VAF 82/336 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- FOXD4L4 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 121/1294 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); called by muse, mutect2
- FRY | c.2894G>A p.G965E | Missense Mutation (SNP) | VAF 140/395 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- FSIP2 | c.19951G>A p.V6651M | Missense Mutation (SNP) | VAF 57/243 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GALNTL6 | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 182/522 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GARRE1 | c.1227G>C p.K409N | Missense Mutation (SNP) | VAF 82/327 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GBP4 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 99/340 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- GIMAP7 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 109/447 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- GMPR | c.841G>A p.G281R | Missense Mutation (SNP) | VAF 51/385 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- GOLGA4 | c.3172C>T p.L1058F | Missense Mutation (SNP) | VAF 87/372 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- GPR152 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 94/436 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- GPR156 | c.1837C>T p.P613S | Missense Mutation (SNP) | VAF 134/610 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- HEATR9 | c.1432G>A p.V478I | Missense Mutation (SNP) | VAF 103/485 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HNRNPA1P48 | c.296A>T p.K99M | Missense Mutation (SNP) | VAF 105/432 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HNRNPA1P48 | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 102/450 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- HRNR | c.7073G>A p.G2358E | Missense Mutation (SNP) | VAF 122/1240 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- HSF2 | c.745T>C p.Y249H | Missense Mutation (SNP) | VAF 82/334 reads (25%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- IGLV2-18 | c.196A>C p.K66Q | Missense Mutation (SNP) | VAF 85/386 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.927); called by muse, varscan2
- IL9R | c.158C>T p.T53I | Missense Mutation (SNP) | VAF 78/389 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.277); called by muse, varscan2
- ILDR1 | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 77/296 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IMPG1 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 98/386 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- IMPG2 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 91/413 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- INTS1 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 45/269 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ITGB6 | c.499A>C p.T167P | Missense Mutation (SNP) | VAF 89/356 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IVL | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 87/502 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- JUND | c.789G>A p.M263I | Missense Mutation (SNP) | VAF 135/537 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- KCNIP1 | c.332C>T p.T111I (on ENST00000411494 / NM_001034837.3; = p.T100I on NM_014592.4) | Missense Mutation (SNP) | VAF 66/306 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KCNV1 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 89/546 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- KIF12 | c.1606C>T p.P536S (on ENST00000640217; = p.P398S on NM_138424.1) | Missense Mutation (SNP) | VAF 87/291 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- KIF17 | c.1876C>T p.L626F | Missense Mutation (SNP) | VAF 79/403 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KIF3B | c.222T>G p.D74E | Missense Mutation (SNP) | VAF 62/327 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KIRREL2 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 103/377 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- KLC3 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 100/408 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KLHL20 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 239/439 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- KLHL22 | c.127C>T p.L43F | Missense Mutation (SNP) | VAF 107/472 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHL5 | c.1868A>T p.K623I | Missense Mutation (SNP) | VAF 87/249 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- KLK11 | c.398G>A p.S133N (on ENST00000594768 / NM_144947.3; = p.S101N on NM_006853.3) | Missense Mutation (SNP) | VAF 107/476 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- KLKB1 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 114/563 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- KLRF2 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 56/247 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- LEMD1 | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 61/345 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- LEMD2 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 144/926 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- LGALS7B | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- LILRB5 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 194/773 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LRP1 | c.9830A>C p.D3277A | Missense Mutation (SNP) | VAF 81/430 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- LRTM1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 105/399 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, varscan2
- LTBP1 | c.942T>A p.F314L | Missense Mutation (SNP) | VAF 87/407 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MACF1 | c.12664C>T p.Q4222* (on ENST00000372915; = p.Q2155* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 120/424 reads (28%) | called by muse, mutect2, varscan2
- MAGOHB | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- MALRD1 | c.3922G>A p.D1308N | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- MAP4K1 | c.2396G>A p.R799K | Missense Mutation (SNP) | VAF 64/301 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- MAP4K1 | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 82/415 reads (20%) | called by muse, mutect2, varscan2
- MATN2 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 112/584 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ME3 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 117/435 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MET | c.3134C>T p.P1045L | Missense Mutation (SNP) | VAF 106/423 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MFSD4A | c.227G>A p.R76K | Missense Mutation (SNP) | VAF 42/282 reads (15%) | SIFT tolerated (0.83); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MICAL2 | c.5182C>T p.P1728S | Missense Mutation (SNP) | VAF 108/495 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.308); called by muse, varscan2
- MMP8 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 73/318 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MMP9 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 85/378 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MOV10L1 | c.308A>C p.E103A | Missense Mutation (SNP) | VAF 85/332 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MTF2 | c.86C>T p.T29I | Missense Mutation (SNP) | VAF 114/467 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MUC12 | c.496G>A p.G166S (on ENST00000379442; = p.X23_splice on NM_001164462.1) | Missense Mutation (SNP) | VAF 102/487 reads (21%) | PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- MUC2 | c.1052C>T p.T351I | Missense Mutation (SNP) | VAF 88/379 reads (23%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MUC7 | c.1111A>T p.I371F | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MYBPC1 | c.3331C>T p.P1111S (on ENST00000550270 / NM_206820.2; = p.P1118S on NM_002465.4) | Missense Mutation (SNP) | VAF 41/282 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- MYH1 | c.4513G>A p.E1505K | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MYH11 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 103/455 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- MYO1H | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 100/363 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- NBPF1 | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 127/592 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- NCAM1 | c.2404G>A p.D802N (on ENST00000316851 / NM_181351.5; = p.D792N on NM_000615.7) | Missense Mutation (SNP) | VAF 76/397 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NCKAP5 | c.3164G>A p.G1055E | Missense Mutation (SNP) | VAF 99/458 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- NEB | c.11833G>A p.D3945N | Missense Mutation (SNP) | VAF 62/255 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- NEK5 | c.1083T>A p.Y361* | Nonsense Mutation (SNP) | VAF 88/528 reads (17%) | called by muse, mutect2, varscan2
- NGEF | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 77/430 reads (18%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- NHS | c.2840C>T p.T947I | Missense Mutation (SNP) | VAF 128/278 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NLRP14 | c.653G>A p.G218E | Missense Mutation (SNP) | VAF 60/344 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- NLRP5 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 112/442 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NPIPB5 | c.1735C>G p.P579A | Missense Mutation (SNP) | VAF 65/682 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.9); called by muse, varscan2
- NSD2 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 94/339 reads (28%) | SIFT tolerated (0.97); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NSUN7 | c.1473G>A p.M491I | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NUB1 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 63/316 reads (20%) | called by muse, mutect2, varscan2
- NUGGC | c.2375C>A p.P792H | Missense Mutation (SNP) | VAF 67/319 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUP210 | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 97/466 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NUTM2G | c.2120G>A p.G707E | Missense Mutation (SNP) | VAF 56/237 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR2A7 | c.217G>C p.A73P | Missense Mutation (SNP) | VAF 70/482 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.134); called by muse, mutect2
- OR2AE1 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 106/466 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- OR4X2 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 88/439 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR52N5 | c.874C>T p.L292F | Missense Mutation (SNP) | VAF 80/397 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- OR7G1 | c.592C>T p.L198F | Missense Mutation (SNP) | VAF 70/343 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- OR9H1P | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 82/431 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OTOG | c.3781G>A p.A1261T | Missense Mutation (SNP) | VAF 133/482 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- OVCH2 | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 57/257 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PABPC3 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 100/551 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- PAK1 | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 120/524 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PAPPA2 | c.5294C>T p.S1765F | Missense Mutation (SNP) | VAF 168/326 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- PARN | c.1622C>T p.P541L | Missense Mutation (SNP) | VAF 109/543 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- PATE3 | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 50/206 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDH10 | c.2555C>T p.P852L | Missense Mutation (SNP) | VAF 205/519 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PEG3 | c.1478G>T p.S493I | Missense Mutation (SNP) | VAF 78/390 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- PIEZO2 | c.4740+1G>A p.X1580_splice | Splice Site (SNP) | VAF 49/219 reads (22%) | called by muse, mutect2, varscan2
- PIEZO2 | c.4740G>A p.Q1580= | Splice Region (SNP) | VAF 49/219 reads (22%) | called by muse, mutect2, varscan2
- PLA2R1 | c.587G>A p.G196D | Missense Mutation (SNP) | VAF 110/472 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLBD1 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 65/306 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLXDC2 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 41/236 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- PLXNB1 | c.3938C>T p.S1313F | Missense Mutation (SNP) | VAF 67/388 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- POLG | c.2718del p.F907Lfs*13 | Frame Shift Del (DEL) | VAF 66/346 reads (19%) | called by mutect2, pindel, varscan2
- POTEA | c.1689G>A p.M563I (on ENST00000519951 / NM_001005365.2; = p.M517I on NM_001002920.1) | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PPIAL4A | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 128/347 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- PRAMEF5 | c.521G>A p.R174K | Missense Mutation (SNP) | VAF 50/404 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRKCA | c.448C>T p.L150F | Missense Mutation (SNP) | VAF 170/587 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- PRPS2 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 113/239 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- PRSS55 | c.767G>A p.R256K | Missense Mutation (SNP) | VAF 57/322 reads (18%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPN1 | c.914A>T p.H305L | Missense Mutation (SNP) | VAF 108/514 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RAD51AP2 | c.3028A>T p.K1010* | Nonsense Mutation (SNP) | VAF 57/303 reads (19%) | called by muse, mutect2, varscan2
- RAG1 | c.2696C>T p.S899L | Missense Mutation (SNP) | VAF 108/458 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- RALYL | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 45/246 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- RAPGEF5 | c.1529G>A p.G510E (on ENST00000401957 / NM_001367602.2; = p.G813E on NM_012294.5) | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAPH1 | c.3461C>T p.S1154F | Missense Mutation (SNP) | VAF 96/478 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RASSF6 | c.470C>T p.S157F (on ENST00000342081 / NM_201431.2; = p.S125F on NM_177532.5) | Missense Mutation (SNP) | VAF 42/269 reads (16%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- RBM20 | c.3631C>T p.P1211S | Missense Mutation (SNP) | VAF 105/309 reads (34%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- RGS22 | c.1444G>A p.G482R | Missense Mutation (SNP) | VAF 55/403 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- RNF111 | c.2960A>G p.E987G (on ENST00000557998 / NM_001270530.1; = p.E979G on NM_017610.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/246 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- RNF213 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 78/592 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF225 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 112/560 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.144); called by muse, varscan2
- RUSC2 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 114/459 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- RYR3 | c.3748G>A p.D1250N | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- S1PR1 | c.1001G>A p.G334E | Missense Mutation (SNP) | VAF 106/436 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SACM1L | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 62/315 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SAMD3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 46/303 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SCN4A | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 171/840 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- SHROOM1 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 123/527 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC17A1 | c.1186G>A p.G396R | Missense Mutation (SNP) | VAF 144/307 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SLC18A3 | c.703C>T p.L235F | Missense Mutation (SNP) | VAF 113/368 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- SLC22A12 | c.671G>A p.W224* | Nonsense Mutation (SNP) | VAF 76/352 reads (22%) | called by muse, mutect2, varscan2
- SLC35G3 | c.337C>T p.L113F | Missense Mutation (SNP) | VAF 118/516 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- SLC4A11 | c.1277G>A p.G426E | Missense Mutation (SNP) | VAF 102/386 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLIT2 | c.3436C>T p.Q1146* | Nonsense Mutation (SNP) | VAF 88/265 reads (33%) | called by muse, mutect2, varscan2
- SMCO2 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 73/317 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- SMIM40 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 62/368 reads (17%) | called by muse, mutect2, varscan2
- SNRPN | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 66/327 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- SOX17 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 312/760 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, varscan2
- SP140 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 79/369 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SP5 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 111/509 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SPATA17 | c.849G>A p.W283* | Nonsense Mutation (SNP) | VAF 154/383 reads (40%) | called by muse, mutect2, varscan2
- SPATA48 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 47/245 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- SPON1 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 55/309 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRMS | c.764T>A p.V255E | Missense Mutation (SNP) | VAF 116/385 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRP54 | c.1229C>T p.S410L | Missense Mutation (SNP) | VAF 64/344 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- SRRM3 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 74/421 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- SRSF1 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 84/695 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SSU72P8 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 121/472 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STIP1 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 94/383 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- STMND1 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 105/563 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- SYT10 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 103/392 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- TAF11L14 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 66/326 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.499); called by muse, varscan2
- TAF11L2 | c.239A>T p.K80M | Missense Mutation (SNP) | VAF 94/437 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- TBC1D2B | c.1991C>T p.P664L | Missense Mutation (SNP) | VAF 109/425 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TCF7L1 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 74/242 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, varscan2
- TCN2 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 103/407 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- TENM3 | c.5582G>A p.S1861N | Missense Mutation (SNP) | VAF 113/342 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- TG | c.4280G>A p.G1427E | Missense Mutation (SNP) | VAF 76/475 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- THBS4 | c.241A>G p.T81A | Missense Mutation (SNP) | VAF 90/366 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- TIE1 | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 144/567 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- TMEM117 | c.431A>T p.Y144F | Missense Mutation (SNP) | VAF 57/245 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM232 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 62/281 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- TMPRSS15 | c.2923T>A p.L975I | Missense Mutation (SNP) | VAF 55/269 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TNFRSF4 | c.461C>T p.T154I | Missense Mutation (SNP) | VAF 85/357 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TNFSF13B | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 56/195 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TNFSF4 | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 105/476 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- TOX | c.339G>A p.M113I | Missense Mutation (SNP) | VAF 103/493 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- TPRX1 | c.1094G>A p.G365E | Missense Mutation (SNP) | VAF 102/433 reads (24%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- TRIM24 | c.11_12insAC p.V5Rfs*137 | Frame Shift Ins (INS) | VAF 68/380 reads (18%) | called by mutect2, pindel, varscan2
- TRIM71 | c.2222G>A p.G741E | Missense Mutation (SNP) | VAF 98/479 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIML1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 98/530 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- TTC33 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 74/339 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- TTLL11 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 128/427 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- TTN | c.719T>C p.V240A | Missense Mutation (SNP) | VAF 64/349 reads (18%) | PolyPhen benign (0.342); called by muse, mutect2, varscan2
- TUB | c.958G>A p.D320N (on ENST00000299506 / NM_177972.3; = p.D375N on NM_003320.4) | Missense Mutation (SNP) | VAF 69/393 reads (18%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- TUBGCP6 | c.4154C>T p.P1385L | Missense Mutation (SNP) | VAF 95/401 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TUSC3 | c.307A>T p.R103W | Missense Mutation (SNP) | VAF 71/273 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- UBR4 | c.14171G>A p.R4724K | Missense Mutation (SNP) | VAF 101/392 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- UCP2 | c.494C>T p.T165I | Missense Mutation (SNP) | VAF 90/401 reads (22%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- UGT2A1 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 59/382 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UNC5C | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 97/432 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- UNC79 | c.907C>T p.P303S (on ENST00000393151 / NM_001346218.2; = p.P126S on NM_020818.5) | Missense Mutation (SNP) | VAF 73/383 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- USP17L1 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 75/336 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UTP25 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 209/361 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- VIL1 | c.2473G>A p.G825R | Missense Mutation (SNP) | VAF 39/251 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WDR87 | c.5390G>A p.R1797K | Missense Mutation (SNP) | VAF 132/504 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- WSB2 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 64/287 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ZBBX | c.1922C>T p.S641F | Missense Mutation (SNP) | VAF 86/372 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- ZBED9 | c.3676A>C p.K1226Q | Missense Mutation (SNP) | VAF 80/576 reads (14%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ZC3H11A | c.1901T>G p.V634G | Missense Mutation (SNP) | VAF 89/446 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZNF257 | c.330T>A p.N110K | Missense Mutation (SNP) | VAF 64/287 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.178); called by mutect2, varscan2
- ZNF469 | c.9013C>T p.P3005S (on ENST00000437464; = p.P3033S on NM_001367624.2) | Missense Mutation (SNP) | VAF 112/539 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- ZNF579 | c.214C>T p.H72Y | Missense Mutation (SNP) | VAF 153/672 reads (23%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- ZNF582 | c.1085C>T p.T362I | Missense Mutation (SNP) | VAF 73/380 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- ZNF680 | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 54/274 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ZNF723 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZNF804A | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 68/367 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- ABCC1 | c.3384C>T p.F1128= | Silent (SNP) | VAF 103/401 reads (26%) | catalogued as rs759212785, COSV60687500; called by muse, mutect2, varscan2
- ABCF1 | c.66C>T p.S22= | Silent (SNP) | VAF 106/657 reads (16%) | catalogued as rs759596698; called by muse, mutect2, varscan2
- AC011005.1 | c.807C>G p.P269= | Silent (SNP) | VAF 135/563 reads (24%) | catalogued as rs1240029341, COSV71955842; called by muse, mutect2, varscan2
- ACAP3 | c.1782C>T p.F594= | Silent (SNP) | VAF 87/462 reads (19%) | catalogued as rs779565432, COSV57640366; called by muse, mutect2, varscan2
- ACE | c.2160C>T p.I720= | Silent (SNP) | VAF 184/629 reads (29%) | called by muse, mutect2, varscan2
- ACSS2 | c.1668G>A p.R556= | Silent (SNP) | VAF 54/256 reads (21%) | called by muse, mutect2, varscan2
- ACTN2 | c.2496C>T p.I832= | Silent (SNP) | VAF 58/354 reads (16%) | catalogued as rs189019392; ClinVar: likely benign; called by muse, varscan2
- ADAMTS3 | c.552G>A p.L184= | Silent (SNP) | VAF 76/432 reads (18%) | called by muse, mutect2, varscan2
- ADD2 | c.273G>A p.A91= | Silent (SNP) | VAF 85/427 reads (20%) | catalogued as rs782016516, COSV52464319; called by muse, mutect2, varscan2
- ADGRE3 | c.1320G>A p.E440= | Silent (SNP) | VAF 72/367 reads (20%) | called by muse, mutect2, varscan2
- ADRA1D | c.649C>T p.L217= | Silent (SNP) | VAF 134/596 reads (22%) | catalogued as rs1244853676; called by muse, mutect2, varscan2
- AKAP11 | c.3831C>T p.V1277= | Silent (SNP) | VAF 130/389 reads (33%) | catalogued as rs758354959; called by muse, mutect2, varscan2
- AKR1C4 | c.354C>T p.F118= | Silent (SNP) | VAF 125/263 reads (48%) | catalogued as rs782452602; called by muse, mutect2, varscan2
- AKR7A3 | c.105C>T p.F35= | Silent (SNP) | VAF 125/564 reads (22%) | called by muse, mutect2, varscan2
- AL669918.1 | c.2343C>T p.I781= | Silent (SNP) | VAF 393/1155 reads (34%) | called by muse, mutect2, varscan2
- ALK | c.1347C>T p.L449= | Silent (SNP) | VAF 120/413 reads (29%) | catalogued as COSV66591953; called by muse, mutect2, varscan2
- ANKK1 | c.1410G>A p.Q470= | Silent (SNP) | VAF 118/455 reads (26%) | catalogued as COSV58274113; called by muse, mutect2, varscan2
- ANKRD11 | c.3273C>T p.F1091= | Silent (SNP) | VAF 71/358 reads (20%) | catalogued as rs1194808663; called by muse, mutect2, varscan2
- ANKRD30A | c.1245G>A p.R415= (on ENST00000611781; = p.R359= on NM_052997.2) | Silent (SNP) | VAF 110/348 reads (32%) | called by muse, mutect2, varscan2
- APOB | c.4080G>A p.T1360= | Silent (SNP) | VAF 111/512 reads (22%) | catalogued as rs374558307, COSV51925218; called by muse, mutect2, varscan2
- ARFGEF3 | c.6147G>A p.K2049= | Silent (SNP) | VAF 130/514 reads (25%) | called by muse, mutect2, varscan2
- ARL14EPL | c.312C>T p.N104= | Silent (SNP) | VAF 94/441 reads (21%) | catalogued as rs1465561985, COSV74124092; called by muse, mutect2, varscan2
- ATG2A | c.4116C>T p.I1372= | Silent (SNP) | VAF 47/219 reads (21%) | catalogued as rs1223066549, COSV101034959; called by muse, mutect2, varscan2
- ATP13A1 | c.1353C>T p.L451= | Silent (SNP) | VAF 72/318 reads (23%) | catalogued as rs868052378; called by muse, mutect2, varscan2
- ATP2B1 | c.1836C>T p.F612= | Silent (SNP) | VAF 65/255 reads (25%) | called by muse, mutect2, varscan2
- AXL | c.762C>T p.P254= | Silent (SNP) | VAF 90/369 reads (24%) | catalogued as rs777619818; called by muse, mutect2, varscan2
- BCOR | c.1035T>G p.L345= | Silent (SNP) | VAF 166/371 reads (45%) | called by muse, mutect2, varscan2
- BNC1 | c.2706G>A p.G902= | Silent (SNP) | VAF 80/378 reads (21%) | called by muse, mutect2, varscan2
- BPIFA1 | c.231G>A p.L77= | Silent (SNP) | VAF 105/405 reads (26%) | called by muse, mutect2, varscan2
- BRD8 | c.897C>T p.P299= (on ENST00000254900 / NM_139199.2; = p.P372= on NM_006696.4) | Silent (SNP) | VAF 74/330 reads (22%) | called by muse, mutect2, varscan2
- BRINP1 | c.2100G>A p.R700= | Silent (SNP) | VAF 104/332 reads (31%) | catalogued as rs763071245, COSV56291917; called by muse, mutect2, varscan2
- BTBD11 | c.2370C>T p.A790= (on ENST00000280758 / NM_001018072.2; = p.A327= on NM_001017523.2) | Silent (SNP) | VAF 93/454 reads (20%) | called by muse, mutect2, varscan2
- C1orf116 | c.894C>T p.P298= | Silent (SNP) | VAF 312/553 reads (56%) | called by muse, mutect2, varscan2
- C2orf49 | c.540G>A p.R180= | Silent (SNP) | VAF 81/304 reads (27%) | called by muse, mutect2, varscan2
- C6orf15 | c.840A>C p.G280= | Silent (SNP) | VAF 82/691 reads (12%) | called by muse, mutect2, varscan2
- CACNG6 | c.759C>T p.P253= (on ENST00000252729 / NM_145814.1; = p.P182= on NM_031897.2) | Silent (SNP) | VAF 101/390 reads (26%) | catalogued as rs1352363507; called by muse, mutect2, varscan2
- CAGE1 | c.756G>A p.K252= (on ENST00000512086; = p.K116= on NM_205864.3) | Silent (SNP) | VAF 80/507 reads (16%) | called by muse, mutect2, varscan2
- CALCR | c.1443G>A p.L481= (on ENST00000649521 / NM_001164737.2; = p.L465= on NM_001742.4) | Silent (SNP) | VAF 55/255 reads (22%) | called by muse, mutect2, varscan2
- CAPN13 | c.972C>T p.F324= | Silent (SNP) | VAF 63/318 reads (20%) | called by muse, mutect2, varscan2
- CARMIL2 | c.3426C>T p.P1142= | Silent (SNP) | VAF 105/528 reads (20%) | called by muse, mutect2, varscan2
- CASR | c.414G>A p.T138= | Silent (SNP) | VAF 101/435 reads (23%) | catalogued as rs984531247, COSV56134702; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCDC169 | c.540G>A p.V180= | Silent (SNP) | VAF 121/328 reads (37%) | called by muse, mutect2, varscan2
- CD14 | c.22T>C p.L8= | Silent (SNP) | VAF 101/419 reads (24%) | called by muse, mutect2, varscan2
- CD19 | c.18C>T p.L6= | Silent (SNP) | VAF 78/337 reads (23%) | called by muse, mutect2, varscan2
- CD300LB | c.315G>A p.G105= | Silent (SNP) | VAF 80/523 reads (15%) | called by muse, mutect2, varscan2
- CDC42BPG | c.3562C>T p.L1188= | Silent (SNP) | VAF 106/494 reads (21%) | called by muse, mutect2, varscan2
- CDHR3 | c.2103G>A p.R701= | Silent (SNP) | VAF 87/360 reads (24%) | called by muse, mutect2, varscan2
- CEP295NL | c.972C>T p.S324= | Silent (SNP) | VAF 104/557 reads (19%) | catalogued as rs1431189238, COSV53159856; called by muse, mutect2, varscan2
- CES5A | c.1074C>T p.I358= | Silent (SNP) | VAF 99/439 reads (23%) | catalogued as COSV99307084; called by muse, mutect2, varscan2
- CFAP221 | c.2421G>A p.V807= | Silent (SNP) | VAF 61/300 reads (20%) | called by muse, mutect2, varscan2
- CHD5 | c.4890C>T p.P1630= | Silent (SNP) | VAF 109/435 reads (25%) | catalogued as rs746787920; called by muse, mutect2, varscan2
- CNOT6 | c.1587T>G p.S529= | Silent (SNP) | VAF 105/474 reads (22%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.693G>A p.L231= | Silent (SNP) | VAF 79/275 reads (29%) | called by muse, mutect2, varscan2
- COL4A5 | c.1530C>T p.F510= | Silent (SNP) | VAF 109/189 reads (58%) | called by muse, mutect2, varscan2
- COL6A5 | c.7587G>A p.G2529= (on ENST00000312481; = p.G2525= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/170 reads (19%) | called by muse, mutect2, varscan2
- CPN2 | c.669C>T p.F223= | Silent (SNP) | VAF 121/543 reads (22%) | called by muse, mutect2, varscan2
- CRHR2 | c.981C>T p.F327= | Silent (SNP) | VAF 97/427 reads (23%) | catalogued as rs754175579; called by muse, mutect2, varscan2
- CROCC2 | c.4587G>A p.E1529= | Silent (SNP) | VAF 73/386 reads (19%) | called by muse, mutect2, varscan2
- CRYBG1 | c.894G>A p.G298= | Silent (SNP) | VAF 100/452 reads (22%) | called by muse, mutect2, varscan2
- CSMD1 | c.5508G>A p.T1836= (on ENST00000520002; = p.T1835= on NM_033225.6) | Silent (SNP) | VAF 43/206 reads (21%) | catalogued as rs774904972; called by muse, mutect2, varscan2
- CSMD2 | c.9832C>T p.L3278= | Silent (SNP) | VAF 91/350 reads (26%) | catalogued as COSV53882668; called by muse, mutect2, varscan2
- CSMD2 | c.1410C>T p.D470= | Silent (SNP) | VAF 67/290 reads (23%) | called by muse, mutect2, varscan2
- CTDP1 | c.1875C>T p.I625= | Silent (SNP) | VAF 130/600 reads (22%) | catalogued as rs774316208, COSV50008750; called by muse, mutect2, varscan2
- CTNNA3 | c.126G>A p.Q42= | Silent (SNP) | VAF 73/232 reads (31%) | called by muse, mutect2, varscan2
- CYB561 | c.189C>T p.F63= | Silent (SNP) | VAF 55/452 reads (12%) | called by muse, mutect2, varscan2
- CYP3A7 | c.516G>A p.L172= | Silent (SNP) | VAF 62/262 reads (24%) | called by muse, mutect2, varscan2
- CYP4F8 | c.228C>T p.V76= | Silent (SNP) | VAF 66/313 reads (21%) | catalogued as rs1446711381; called by muse, mutect2, varscan2
- DGKH | c.954C>T p.S318= | Silent (SNP) | VAF 54/282 reads (19%) | catalogued as rs374539521; called by muse, mutect2, varscan2
- DISP2 | c.1272G>A p.Q424= | Silent (SNP) | VAF 113/431 reads (26%) | called by muse, mutect2, varscan2
- DNAI2 | c.975C>T p.F325= | Silent (SNP) | VAF 149/306 reads (49%) | catalogued as rs1217838487; called by muse, mutect2, varscan2
- DNAJC16 | c.663C>T p.I221= | Silent (SNP) | VAF 99/395 reads (25%) | called by muse, mutect2, varscan2
- DNM2 | c.405C>T p.I135= | Silent (SNP) | VAF 38/241 reads (16%) | catalogued as rs1321286721, COSV58961976; called by muse, varscan2
- DOP1B | c.3624C>T p.S1208= | Silent (SNP) | VAF 91/432 reads (21%) | called by muse, mutect2, varscan2
- DRD5 | c.363C>T p.I121= | Silent (SNP) | VAF 94/328 reads (29%) | catalogued as COSV58576576; called by muse, varscan2
- DRD5 | c.504C>T p.S168= | Silent (SNP) | VAF 96/303 reads (32%) | catalogued as COSV58579589; called by muse, varscan2
- DSC2 | c.1752C>T p.I584= | Silent (SNP) | VAF 71/362 reads (20%) | catalogued as rs367583109; called by muse, mutect2, varscan2
- DXO | c.462C>T p.S154= | Silent (SNP) | VAF 168/936 reads (18%) | called by muse, mutect2, varscan2
- DYSF | c.1278G>A p.G426= | Silent (SNP) | VAF 58/305 reads (19%) | catalogued as COSV99245061; called by muse, mutect2, varscan2
- EDC3 | c.444C>T p.S148= | Silent (SNP) | VAF 85/327 reads (26%) | called by muse, mutect2, varscan2
- EIF4ENIF1 | c.816C>A p.A272= | Silent (SNP) | VAF 63/326 reads (19%) | called by muse, mutect2, varscan2
- ELFN2 | c.78C>T p.L26= | Silent (SNP) | VAF 117/520 reads (23%) | catalogued as rs1315458119, COSV68744686; called by muse, mutect2, varscan2
- EP400 | c.7779C>G p.A2593= | Silent (SNP) | VAF 78/355 reads (22%) | catalogued as rs749457156; called by muse, mutect2, varscan2
- EPPK1 | c.1134C>T p.F378= | Silent (SNP) | VAF 112/609 reads (18%) | called by muse, mutect2, varscan2
- ERFE | c.87C>T p.S29= | Silent (SNP) | VAF 98/397 reads (25%) | called by muse, mutect2, varscan2
- ERVFRD-1 | c.675G>A p.A225= | Silent (SNP) | VAF 54/401 reads (13%) | catalogued as rs559395063, COSV65368702; called by muse, mutect2, varscan2
- ESPN | c.2355C>T p.P785= | Silent (SNP) | VAF 69/284 reads (24%) | called by muse, mutect2, varscan2
- F13A1 | c.618C>T p.V206= | Silent (SNP) | VAF 80/504 reads (16%) | catalogued as rs1325123079; called by muse, mutect2, varscan2
- FADS6 | c.1101G>A p.G367= | Silent (SNP) | VAF 61/472 reads (13%) | called by muse, mutect2, varscan2
- FAM181A | c.849G>A p.Q283= | Silent (SNP) | VAF 138/583 reads (24%) | catalogued as rs750801341, COSV50889693; called by muse, mutect2, varscan2
- FAM47C | c.2058C>T p.R686= | Silent (SNP) | VAF 110/245 reads (45%) | called by muse, mutect2, varscan2
- FBN3 | c.6726C>T p.P2242= | Silent (SNP) | VAF 130/537 reads (24%) | called by muse, mutect2, varscan2
- FBRSL1 | c.3117C>T p.P1039= | Silent (SNP) | VAF 70/351 reads (20%) | called by muse, mutect2, varscan2
- FBXW7 | c.1968T>C p.F656= (on ENST00000281708 / NM_001349798.2; = p.F576= on NM_018315.5) | Silent (SNP) | VAF 95/517 reads (18%) | called by muse, mutect2, varscan2
- FCRL1 | c.666G>A p.E222= | Silent (SNP) | VAF 78/440 reads (18%) | called by muse, mutect2, varscan2
- FCRL5 | c.2556C>T p.V852= | Silent (SNP) | VAF 65/390 reads (17%) | catalogued as rs746651299; called by muse, mutect2, varscan2
- FCRL6 | c.45G>A p.G15= | Silent (SNP) | VAF 81/434 reads (19%) | called by muse, mutect2, varscan2
- FHAD1 | c.3828G>A p.R1276= | Silent (SNP) | VAF 67/311 reads (22%) | catalogued as rs781685775, COSV58990869; called by muse, mutect2, varscan2
- FHAD1 | c.4056C>T p.A1352= | Silent (SNP) | VAF 107/389 reads (28%) | called by muse, mutect2, varscan2
- FIGN | c.1671C>T p.A557= | Silent (SNP) | VAF 95/418 reads (23%) | called by muse, mutect2, varscan2
- FLG | c.3516G>A p.R1172= | Silent (SNP) | VAF 124/719 reads (17%) | catalogued as rs201350571, COSV100911497, COSV100912300; called by muse, mutect2, varscan2
- FLT1 | c.1986C>T p.Y662= | Silent (SNP) | VAF 127/365 reads (35%) | called by muse, mutect2, varscan2
- FSHR | c.1707G>A p.R569= | Silent (SNP) | VAF 83/408 reads (20%) | called by muse, mutect2, varscan2
- FYB2 | c.399C>T p.A133= | Silent (SNP) | VAF 90/442 reads (20%) | called by muse, mutect2, varscan2
- FZD2 | c.885C>T p.I295= | Silent (SNP) | VAF 111/448 reads (25%) | called by muse, mutect2, varscan2
- GABRR1 | c.303G>A p.V101= | Silent (SNP) | VAF 62/338 reads (18%) | called by muse, mutect2, varscan2
- GAL3ST2 | c.99G>A p.S33= | Silent (SNP) | VAF 126/456 reads (28%) | catalogued as rs758338326, COSV51952166; called by muse, varscan2
- GALNT15 | c.1650G>A p.R550= | Silent (SNP) | VAF 98/375 reads (26%) | called by muse, mutect2, varscan2
- GBF1 | c.2346C>T p.A782= (on ENST00000369983 / NM_001377137.1; = p.A781= on NM_004193.3) | Silent (SNP) | VAF 70/265 reads (26%) | called by muse, mutect2, varscan2
- GCC1 | c.1056C>T p.L352= | Silent (SNP) | VAF 48/221 reads (22%) | called by muse, mutect2, varscan2
- GIMAP4 | c.444C>T p.F148= | Silent (SNP) | VAF 104/358 reads (29%) | catalogued as COSV55433255; called by muse, mutect2, varscan2
- GIMAP8 | c.1708C>T p.L570= | Silent (SNP) | VAF 94/491 reads (19%) | catalogued as rs755463565, COSV56230013; called by muse, mutect2, varscan2
- GJC1 | c.501G>A p.R167= | Silent (SNP) | VAF 93/481 reads (19%) | called by muse, mutect2, varscan2
- GLP2R | c.435G>A p.T145= | Silent (SNP) | VAF 82/227 reads (36%) | catalogued as rs145225948; called by muse, mutect2, varscan2
- GNA11 | c.1044C>T p.I348= | Silent (SNP) | VAF 92/391 reads (24%) | called by muse, mutect2, varscan2
- GOLGA6L7 | c.33G>A p.L11= | Silent (SNP) | VAF 66/258 reads (26%) | called by muse, mutect2, varscan2
- GPRASP1 | c.954G>A p.R318= | Silent (SNP) | VAF 114/265 reads (43%) | called by muse, mutect2, varscan2
- GPX5 | c.558C>T p.F186= | Silent (SNP) | VAF 98/770 reads (13%) | catalogued as COSV69079594; called by muse, mutect2, varscan2
- GRAMD1B | c.1200G>A p.R400= | Silent (SNP) | VAF 69/330 reads (21%) | called by muse, mutect2, varscan2
- GTF2IRD1 | c.2256C>T p.F752= (on ENST00000265755 / NM_016328.3; = p.F737= on NM_005685.4) | Silent (SNP) | VAF 120/510 reads (24%) | catalogued as rs782089689, COSV56084719; called by muse, mutect2, varscan2
- HAPLN3 | c.276G>A p.S92= | Silent (SNP) | VAF 121/510 reads (24%) | catalogued as rs148751452; called by muse, mutect2, varscan2
- HCN1 | c.1524G>A p.V508= | Silent (SNP) | VAF 58/258 reads (22%) | called by muse, mutect2, varscan2
- HECA | c.985T>C p.L329= | Silent (SNP) | VAF 88/423 reads (21%) | called by muse, mutect2, varscan2
- HLA-DRA | c.711C>T p.F237= | Silent (SNP) | VAF 107/750 reads (14%) | catalogued as COSV66623033; called by muse, mutect2, varscan2
- HOXB1 | c.48C>T p.N16= | Silent (SNP) | VAF 73/362 reads (20%) | catalogued as rs761478151; called by muse, mutect2, varscan2
- HP | c.102G>A p.P34= | Silent (SNP) | VAF 25/204 reads (12%) | catalogued as rs768497633, COSV100577485; called by muse, mutect2, varscan2
- HS3ST6 | c.420G>A p.L140= | Silent (SNP) | VAF 75/286 reads (26%) | called by muse, mutect2
- HTR1E | c.786C>T p.S262= | Silent (SNP) | VAF 92/361 reads (25%) | called by muse, mutect2, varscan2
- HYDIN | c.12462C>T p.F4154= | Silent (SNP) | VAF 65/255 reads (25%) | catalogued as COSV66641153; called by muse, mutect2, varscan2
- HYDIN | c.12414C>T p.P4138= | Silent (SNP) | VAF 52/251 reads (21%) | called by muse, mutect2, varscan2
- HYDIN | c.8235C>T p.I2745= | Silent (SNP) | VAF 27/163 reads (17%) | called by muse, mutect2, varscan2
- IDUA | c.1482C>T p.V494= | Silent (SNP) | VAF 96/296 reads (32%) | called by muse, mutect2, varscan2
- IFI27L1 | c.99C>T p.A33= | Silent (SNP) | VAF 105/454 reads (23%) | called by muse, mutect2, varscan2
- IFT52 | c.372C>T p.F124= | Silent (SNP) | VAF 59/293 reads (20%) | catalogued as COSV65974596; called by muse, mutect2, varscan2
- IGHV4-59 | c.72G>A p.Q24= | Silent (SNP) | VAF 132/1138 reads (12%) | catalogued as rs782724583; called by muse, varscan2
- IGKV1-9 | c.15C>T p.V5= | Silent (SNP) | VAF 100/514 reads (19%) | called by muse, mutect2
- IGSF10 | c.93C>T p.R31= | Silent (SNP) | VAF 101/429 reads (24%) | called by muse, mutect2, varscan2
- IKZF2 | c.921G>A p.K307= | Silent (SNP) | VAF 88/425 reads (21%) | called by muse, mutect2, varscan2
- IL5RA | c.108C>T p.F36= | Silent (SNP) | VAF 56/267 reads (21%) | called by muse, mutect2, varscan2
- INPP5J | c.2736C>T p.S912= (on ENST00000331075 / NM_001284285.2; = p.S544= on NM_001002837.2) | Silent (SNP) | VAF 109/557 reads (20%) | called by muse, mutect2, varscan2
- IQSEC3 | c.1959G>A p.R653= (on ENST00000538872 / NM_001170738.2; = p.R350= on NM_015232.1) | Silent (SNP) | VAF 81/476 reads (17%) | catalogued as COSV100406858; called by muse, mutect2
277 further variants in this file (0 protein-altering or splice-affecting, 224 silent, 53 other) are not listed here.
